Gene-level copy-number profile of tumor specimen TCGA-LD-A7W5-01A from TCGA case TCGA-LD-A7W5, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 52.5 years (19,169 days).
Specimen TCGA-LD-A7W5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.ac9fab7a-b830-4ebe-bd2c-939c812d7826.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LD-A7W5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/62a2c376-66e8-4a64-9940-72fafcf10f41

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 13,874; copy number 2: 41,795; copy number 3: 3,270; copy number 4: 353; copy number 5: 39; copy number 6: 1; copy number 7: 78; copy number 8: 5; copy number 9: 2; copy number 10: 104; copy number 11: 25; copy number 12: 13; copy number 13: 73; copy number 14: 1; copy number 15: 15; copy number 17: 31; copy number 19: 37; copy number 22: 17; copy number 26: 7; copy number 30: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LD-A7W5-01A-22D-A350-01): tumor purity 0.26, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:6,057,807–6,323,228, 4 genes: WSCD1, AC104770.1, RNU6-1264P, BTF3P14.
- chr17:8,729,935–10,198,606, 30 genes: CCDC42, SPDYE4, MFSD6L, PIK3R6, PIK3R5, AC002091.2, AC002091.1, NTN1, AC005695.1, AC005695.3, STX8, AC005695.2, AC087501.1, AC087501.2, AC087501.3, AC087501.4, CFAP52, RPL19P18, AC118755.2, USP43, AC118755.1, AC027045.2, DHRS7C, AC027045.1, GSG1L2, AC027045.3, GLP2R, NPM1P45, RCVRN, GAS7.
- chr17:11,598,470–12,991,643, 17 genes (within-gene range 0–1): DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, AC084167.1, LINC00670, AC068442.1, MYOCD, MYOCD-AS1, AC005358.1, ARHGAP44.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 466 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–46,870, 1 gene, copy number 5: FAM110C.
- chr3:115,802,363–117,139,389, 5 genes, copy number 5–8 (within-gene range 1–8): LSAMP, RN7SL815P, LSAMP-AS1, LINC00903, RN7SL582P.
- chr3:181,146,233–181,146,463, 1 gene, copy number 7: AC083904.1.
- chr5:13,690,331–14,992,961, 19 genes, copy number 13–22 (within-gene range 2–22): DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, AC016575.2.
- chr8:119,165,034–119,673,453, 10 genes, copy number 15 (within-gene range 2–15): MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23.
- chr9:2,421,597–3,200,445, 10 genes, copy number 7: VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231.
- chr9:31,253,901–31,645,160, 5 genes, copy number 7: SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.
- chr10:59,578,467–62,096,944, 22 genes, copy number 8–19 (within-gene range 1–19): AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B.
- chr10:67,750,284–68,261,499, 18 genes, copy number 11–17: AKR1B10P1, RPL21P92, DNAJC12, RNU6-1250P, RN7SL394P, DNAJC19P1, AL133551.1, RNU6-523P, SIRT1, HERC4, RPS3AP38, RN7SL220P, POU5F1P5, MYPN, RN7SKP202, ATOH7, LINC02640, KRT19P4.
- chr10:69,265,342–70,146,700, 23 genes, copy number 17: AL596223.2, HK1, RPS15AP28, TACR2, ATP5MC1P7, TSPAN15, AC016821.1, TMEM256P1, NEUROG3, AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20, FAM241B, LINC02651, RPL5P26, COL13A1, LINC02636, MACROH2A2, AIFM2, TYSND1.
- chr10:74,151,202–75,431,588, 33 genes, copy number 13–30 (within-gene range 2–30): ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2.
- chr10:75,450,081–75,451,725, 1 gene, copy number 13: AC010997.6.
- chr10:78,696,062–79,526,631, 12 genes, copy number 6–12: AC016820.1, ZMIZ1-AS1, AL356753.1, ZMIZ1, PPIF, ZCCHC24, AL133481.1, TPRX1P1, AL133481.3, AL133481.2, EIF5AL1, BX248123.1.
- chr10:81,136,540–81,137,335, 1 gene, copy number 13: RPA2P2.
- chr10:111,322,778–111,498,941, 3 genes, copy number 15: BTBD7P2, AC021035.1, RPS6P15.
- chr10:112,149,865–112,305,038, 2 genes, copy number 12 (within-gene range 1–12): GPAM, TECTB.
- chr10:115,819,842–115,820,487, 1 gene, copy number 14: NTAN1P1.
- chr10:120,608,580–122,898,615, 40 genes, copy number 19–26 (within-gene range 1–26): AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P, PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, AL603764.1, AL603764.2, C10orf120, DMBT1L1, CUZD1, AC073585.1, FAM24B, C10orf88B.
- chr10:129,621,988–129,702,117, 2 genes, copy number 9: AL355531.1, AL157832.2.
- chr16:14,974,591–15,857,028, 29 genes, copy number 7 (within-gene range 4–7): PDXDC1, AC138932.2, MIR1972-1, AC138932.4, NTAN1, RRN3, AC139256.1, NPIPP1, PKD1P6-NPIPP1, PKD1P6, MIR6511B2, Y_RNA, MIR3180-4, AC126763.1, AC137803.1, NPIPA5, MPV17L, AC140504.1, BMERB1, MARF1, AC026401.1, MIR6506, NDE1, MIR484, AC026401.2, AC026401.3, MYH11, AF001548.2, AF001548.1.
- chr17:37,489,891–38,405,593, 26 genes, copy number 5–10: DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45, GPR179, SOCS7.
- chr17:46,833,201–47,223,679, 16 genes, copy number 5: WNT9B, LINC01974, AC005670.1, RNU6ATAC3P, GOSR2, AC005670.2, MIR5089, RPRML, LRRC37A17P, AC005670.3, RN7SL270P, CDC27, AC002558.1, AC002558.3, AC002558.2, MYL4.
- chr17:58,166,982–58,985,179, 33 genes, copy number 7 (within-gene range 1–7): OR4D2, EPX, AC005962.1, MKS1, LPO, AC005962.2, AC004687.3, MPO, TSPOAP1, TSPOAP1-AS1, AC004687.1, MIR142, MIR4736, SUPT4H1, AC004687.2, RNF43, HSF5, SETP3, MTMR4, SEPTIN4-AS1, SEPTIN4, TEX14, U3, IGBP1P2, RNU1-108P, AC011195.1, RNU1-52P, RNVU1-34, RAD51C, AC025521.1, PPM1E, Metazoa_SRP, RNU6-518P.
- chr17:59,422,088–60,666,280, 50 genes, copy number 13: LINC01476, RNU4-13P, DHX40, AC091271.1, CLTC, PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.5, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P.
- chr17:60,696,313–60,900,185, 6 genes, copy number 13: RN7SL606P, AC110602.1, Y_RNA, KRT18P61, HMGN1P28, RN7SL448P.
- chr17:61,361,668–64,130,819, 97 genes, copy number 10 (within-gene range 1–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,874. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
